Somatic mutation profile of tumor specimen TCGA-B8-4143-01A (aliquot TCGA-B8-4143-01A-01D-1806-10) from TCGA case TCGA-B8-4143, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 66.1 years (24,132 days).
Specimen TCGA-B8-4143-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6da87db7-50ea-47dd-9dc8-989fde811ee2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B8-4143-11A (Solid Tissue Normal), aliquot TCGA-B8-4143-11A-01D-1251-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1f6d594e-6f6e-48a8-a4c5-d7ae95885720

The open-access MAF lists 65 somatic variants for this specimen: 50 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 14, Nonsense Mutation 4, Splice Site 2, Frame Shift Del 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHCYL2 | c.1697C>A p.P566H | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61485029, COSV61490197; called by muse, mutect2, varscan2
- AMPD1 | c.1123A>T p.K375* | Nonsense Mutation (SNP) | VAF 42/149 reads (28%) | catalogued as COSV62417973; called by muse, mutect2, varscan2
- ANKRD44 | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 21/179 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV56562516; called by muse, mutect2, varscan2
- ATP8A2 | c.2902G>A p.A968T | Missense Mutation (SNP) | VAF 46/124 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV54969687; called by muse, mutect2, varscan2
- BAP1 | c.1881C>G p.Y627* | Nonsense Mutation (SNP) | VAF 21/38 reads (55%) | catalogued as COSV56238863, COSV99964082, COSV99964557; called by muse, mutect2, varscan2
- BAZ2B | c.3738G>T p.W1246C | Missense Mutation (SNP) | VAF 42/171 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.962); catalogued as COSV54276500; called by muse, mutect2, varscan2
- CAPN1 | c.1913A>G p.Y638C | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99658685; called by muse, mutect2
- CARMIL1 | c.103G>T p.E35* | Nonsense Mutation (SNP) | VAF 34/238 reads (14%) | catalogued as COSV61522243; called by muse, varscan2
- CHRM5 | c.813G>A p.W271* | Nonsense Mutation (SNP) | VAF 7/16 reads (44%) | catalogued as COSV67247039; called by muse, mutect2, varscan2
- CLDN6 | c.468A>C p.Q156H | Missense Mutation (SNP) | VAF 2/24 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.275); catalogued as rs1275738753; called by muse, mutect2
- COL22A1 | c.1283G>T p.R428I | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV57353196; called by muse, mutect2, varscan2
- CRISP2 | c.235A>G p.T79A | Missense Mutation (SNP) | VAF 33/154 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as COSV59256379; called by muse, mutect2, varscan2
- CUBN | c.5950A>T p.T1984S | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.078); catalogued as rs1457485279, COSV64723798; called by muse, varscan2
- EIF4E2 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV51472995; called by muse, mutect2, varscan2
- ESPL1 | c.5797-1G>T p.X1933_splice | Splice Site (SNP) | VAF 11/35 reads (31%) | catalogued as COSV54476743; called by muse, mutect2, varscan2
- GCA | c.136A>G p.T46A | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV52026497; called by muse, mutect2, varscan2
- GNAT2 | c.308A>G p.D103G | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as COSV63555261; called by muse, mutect2, varscan2
- GRB7 | c.583C>T p.P195S | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.286); catalogued as COSV58450016; called by muse, mutect2, varscan2
- GRIN2B | c.905C>T p.T302I | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.847); catalogued as COSV74206894, COSV74207228; called by muse, mutect2
- H2BC11 | c.98G>A p.S33N | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); catalogued as rs137867381, COSV60361691; called by muse, mutect2, varscan2
- HNRNPD | c.370G>A p.V124I | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.055); catalogued as COSV58314585; called by muse, mutect2, varscan2
- HYDIN | c.6399G>T p.M2133I | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV59266207; called by muse, mutect2, varscan2
- INTS13 | c.1535C>G p.P512R | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53904673; called by muse, mutect2, varscan2
- ITPR2 | c.7465G>A p.V2489M | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV67264302; called by muse, mutect2, varscan2
- KIAA1210 | c.4876C>G p.P1626A | Missense Mutation (SNP) | VAF 52/205 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV68179196; called by muse, mutect2, varscan2
- KIF15 | c.1954C>T p.H652Y | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV58163900; called by muse, mutect2, varscan2
- LIPN | c.944A>C p.N315T | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68384363; called by muse, mutect2, varscan2
- MIPOL1 | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 41/74 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59390694; called by muse, mutect2, varscan2
- MRC1 | c.3278C>T p.T1093M | Missense Mutation (SNP) | VAF 33/154 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs1486395056; called by muse, mutect2, varscan2
- MRTFB | c.748G>A p.D250N | Missense Mutation (SNP) | VAF 53/143 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); catalogued as COSV57960593; called by muse, mutect2, varscan2
- MYO1G | c.2092A>T p.T698S | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.864); catalogued as COSV51856460; called by muse, mutect2, varscan2
- NDUFAF1 | c.232C>G p.P78A | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as COSV52976135; called by muse, mutect2, varscan2
- OR4P4 | c.722A>G p.H241R | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58923213; called by muse, mutect2, varscan2
- PKD2L1 | c.969G>T p.E323D | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58398064; called by muse, mutect2, varscan2
- PXDN | c.3490G>A p.D1164N | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs967825855, COSV53243344; called by muse, mutect2, varscan2
- RCBTB2 | c.896A>T p.Y299F | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.66); PolyPhen benign (0.216); catalogued as COSV60651459; called by muse, mutect2, varscan2
- RECQL5 | c.1000T>G p.W334G | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58644816; called by muse, mutect2, varscan2
- RIPPLY3 | c.346T>C p.S116P | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as COSV61567072; called by muse, mutect2, varscan2
- RTP5 | c.1641G>C p.W547C | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.993); catalogued as rs541145009, COSV58321356; called by muse, mutect2, varscan2
- SMO | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs762783453, COSV50826289; called by muse, mutect2, varscan2
- SOX9 | c.1332C>A p.D444E | Missense Mutation (SNP) | VAF 163/364 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV55427200; called by muse, mutect2, varscan2
- SYVN1 | c.1484A>G p.H495R (on ENST00000377190 / NM_172230.3; = p.H494R on NM_032431.3) | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.025); catalogued as COSV53696821; called by muse, mutect2
- TTN | c.93542A>C p.D31181A (on ENST00000591111; = p.D23757A on NM_003319.4) | Missense Mutation (SNP) | VAF 23/86 reads (27%) | PolyPhen probably damaging (0.998); catalogued as rs191054704, COSV60258016; called by muse, mutect2, varscan2
- UGT2A1 | c.1027G>A p.A343T | Missense Mutation (SNP) | VAF 59/169 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV54145374; called by muse, mutect2, varscan2
- ZBTB16 | c.398C>T p.T133M | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.197); catalogued as rs370480903; called by muse, mutect2, varscan2
- ZNF684 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV65519518; called by muse, mutect2, varscan2
- ABL2 | c.688-1G>A p.X230_splice (on ENST00000502732 / NM_007314.4; = p.X215_splice on NM_005158.5) | Splice Site (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2
- ADGRF2 | c.1453del p.H485Mfs*12 (on ENST00000296862 / NM_001368115.2; = p.H417Mfs*12 on NM_153839.7) | Frame Shift Del (DEL) | VAF 18/54 reads (33%) | called by mutect2, pindel
- MROH1 | c.1486C>T p.R496C | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- TMEM165 | c.711del p.F237Lfs*7 | Frame Shift Del (DEL) | VAF 19/94 reads (20%) | called by mutect2, pindel, varscan2
- CENPB | c.1542T>C p.S514= | Silent (SNP) | VAF 38/125 reads (30%) | catalogued as COSV60144691; called by muse, mutect2, varscan2
- COL6A3 | c.3696G>A p.R1232= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as COSV55102990; called by muse, mutect2, varscan2
- DPY19L1 | c.579G>A p.L193= | Silent (SNP) | VAF 28/113 reads (25%) | catalogued as COSV60583644; called by muse, mutect2, varscan2
- HUWE1 | c.7845C>A p.I2615= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV53359352; called by muse, mutect2, varscan2
- KMT2D | c.3033G>A p.P1011= | Silent (SNP) | VAF 32/152 reads (21%) | catalogued as rs373881433; called by muse, mutect2, varscan2
- KRTAP13-1 | c.54C>T p.Y18= | Silent (SNP) | VAF 21/66 reads (32%) | catalogued as COSV62664102; called by muse, mutect2, varscan2
- OR11L1 | c.378C>T p.I126= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV100869419; called by muse, mutect2
- PKHD1 | c.7242G>T p.L2414= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as COSV61890029; called by muse, varscan2
- PLCB3 | c.2061G>A p.A687= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs372858684; called by muse, mutect2, varscan2
- RBM39 | c.648A>G p.Q216= | Silent (SNP) | VAF 32/97 reads (33%) | catalogued as COSV53617143; called by muse, mutect2, varscan2
- RDX | c.6G>T p.P2= | Silent (SNP) | VAF 28/125 reads (22%) | catalogued as COSV58195848; called by muse, varscan2
- SLC4A10 | c.357A>G p.T119= | Silent (SNP) | VAF 37/139 reads (27%) | catalogued as COSV55793667; called by muse, mutect2, varscan2
- TELO2 | c.1236C>T p.V412= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs754820309, COSV51980358; called by muse, mutect2, varscan2
- TMOD1 | c.558G>A p.T186= | Silent (SNP) | VAF 57/84 reads (68%) | catalogued as rs755991791, COSV52251445, COSV99403801; called by muse, mutect2, varscan2
- ANAPC11 | c.110-550G>A | Intron (SNP) | VAF 30/53 reads (57%) | catalogued as rs770056495, COSV58712186, COSV58712353; called by muse, mutect2, varscan2
